Surgical pathology report (de-identified scan), TCGA case TCGA-AG-A011, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-A011-01A (Primary Tumor).

Sample ID #

Diagnosis:

- 1.: Resectate of the rectum with a mainly poorly differentiated adenocarcinoma, with infiltration of the pericolic fatty tissue, tumor-free resection margins and tumor-free lymph nodes (fourteen lymph nodes examined).
- 2.: Superficial splenic tissue with capsule defects and hemorrhaging. No indication of malignancy.

Tumor classification: adenocarcinoma G3, pT3 N0 (0/14) L0 V0 R0.

ICD-0-3

Adenocarcinoma, NOS 8140/3

Site: Rectum C20.9 bx 3/31/11

ICD-PA Discrepancy		X
Primary Malignancy History		X

Source: NCI Genomic Data Commons file 9440b3dc-2ca5-4a62-9c8d-3548be1dc191 (TCGA-AG-A011.33EB55D3-B99D-40A6-80B4-3D11403F4E06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).